Surgical pathology report (de-identified scan), TCGA case TCGA-20-1682, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Fox Chase Cancer Center, specimen TCGA-20-1682-01A (Primary Tumor).

[page 1 of 3]
TCGA-20-1682

Age: [REDACTED]

Sex: [REDACTED]

Clinical History/Diagnosis [REDACTED]

Source of Specimen(s):

- 1: Omentum, resection other than for tumor
- 2: right tube and ovary
- 3: left tube and ovary
- 4: supracervical uterus
- 5: left paracolic gutter

Gross Description:

Received in five parts.

Source of Tissue: 1. Labeled # 1, "omentum"

Gross Description: Received fresh in a container labeled " patient name and medical number, omentum". It consists of a segment of omentum measuring 30.0 x 12.0 x 2.0 cm. Approximately one-third of the omentum has an omental caking and sections show solid tan firm tumor.

Representative sections are submitted in 1A-C.

Source of Tissue: 2. Labeled # 2, "right tube and ovary"

Gross Description: Received fresh in a container labeled " patient name and medical number, right tube and ovary". It consists of an irregular ragged possible ovary having an overall measurement of 12.0 x 10.0 x 6.9 cm. Centrally a markedly distorted fallopian tube is present measuring 4.0 x 1.0 cm and is partially involved by lesion. Sections disclose multiple smooth-walled cysts containing blood-tinged to yellow thin fluid. The cysts measure from 0.6 up to 7.0 cm. Elsewhere, the ovary has a tan to brown friable predominantly necrotic tumor. No normal ovarian structures are found.

Designation of Sections: 2A- potential fallopian tube, 2B-2E- right ovarian tumor

Source of Tissue: 3. Labeled # 3, "left tube and ovary"

Gross Description: Received fresh in a container labeled " patient name and medical number, left tube and ovary". It consists of a ragged rubbery ovary measuring 7.0 x 6.5 x 5.0 cm. Externally there is some

[page 2 of 3]
tumor studding measuring up to 1.0 cm. The fallopian tube with fimbria measures 4.0 x 1.0 x 1.0 cm and is potentially involved with lesional tissue. Sections disclose a 5.0 cm cyst containing brown thin fluid. Some normal ovarian structures are present. The wall is white to firm suggestive of lesion. The tumor involves 75% of the ovary. Representative sections of the ovary with tumor are submitted in 3A-3C and fallopian tube is in 3D.

Source of Tissue: 4. Labeled # 4, "uterus"

Gross Description: Received fresh in a container labeled " patient name and medical number, uterus". It consists of a supracervical hysterectomy specimen consisting of corpus uteri weighing 160-grams and measuring overall 8.5 x 7.5 x 6.2 cm. The specimen is asymmetrical distorted due to numerous serosal adhesions and what appears to be an appreciable amount of tumor studding on the cornua. The cervical stump measures 1.9 cm and is unremarkable. The uterus is bivalved disclosing endometrial cavity measuring 2.5 cm from cornu to cornu and lined by a 0.2 cm endometrium. The myometrium measures up to 1.9 cm in thickness and in the posterior wall there appears to be tumor invading from the serosa. The tumor comes to within 1.5 cm from the endometrium [4C & 4D]. Representative sections are submitted in 4A-G.

Designation of Sections: 4A-4B- adhesions on serosa at cornu, 4C-4D- posterior endomyometrium with tumor invading from outside in, 4E- anterior endomyometrium, 4F- anterior lower uterine segment/cervical stump, 4G- posterior lower uterine segment/cervical stump

Source of Tissue: 5. Left paracolic gutter submitted for [REDACTED]

Final Diagnosis:

1. Omentum:

Serous adenocarcinoma.

2. Right tube and ovary:

Serous adenocarcinoma involving ovary and fallopian tube.

3. Left tube and ovary:

Serous adenocarcinoma involving ovary and fallopian tube.

- Angiolymphatic invasion is identified.

4. Uterus:

Serous adenocarcinoma involving uterine serosa with invasion into outer

[page 3 of 3]
one-third of myometrium.
Inactive endometrium.
Endocervix with no tumor seen.

[REDACTED]

Source: NCI Genomic Data Commons file 6d943c8a-29ee-4720-924c-8236f3639c39 (TCGA-20-1682.CF49EA4D-478C-469D-ACE2-7EF52B66A332.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).